Somatic mutation profile of tumor specimen C3N-02249-75 (aliquot CPT0129080006) from CPTAC case C3N-02249, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G2.
Specimen C3N-02249-75: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1923a122-6f03-496f-a22b-33ed39ccbfb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02249-31 (Blood Derived Normal), aliquot CPT0130810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e3d6ea3-deb7-4649-ab56-b8a055592577

The open-access MAF lists 81 somatic variants for this specimen: 65 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 12, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 3, 5'UTR 2, Frame Shift Ins 2, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 161/400 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 240/613 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52782930, COSV52787207, COSV52795259; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.325del p.E109Kfs*3 | Frame Shift Del (DEL) | VAF 171/521 reads (33%) | catalogued as rs587781716, COSV56222390; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.254-1G>A p.X85_splice | Splice Site (SNP) | VAF 105/308 reads (34%) | hotspot (GDC flag); catalogued as rs1057520208, COSV100910231, COSV64295507; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTEN | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 168/470 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CLVS1 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs757843779; called by muse, mutect2, varscan2
- CNTN2 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 182/471 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs761461194, COSV59351183; called by muse, mutect2, varscan2
- COL12A1 | c.5858G>A p.R1953H | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs367908043; called by muse, mutect2, varscan2
- CPA6 | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs748121520; called by muse, mutect2, varscan2
- CTNNBIP1 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs770182367, COSV101032920; called by muse, mutect2, varscan2
- CYP11B1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 199/595 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs1349746694; called by muse, mutect2, varscan2
- CYP3A7 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs753175222, COSV60482898; called by muse, mutect2, varscan2
- DCC | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749558240, COSV59091020, COSV59105732; called by muse, mutect2, varscan2
- DHX37 | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58136203; called by muse, mutect2, varscan2
- DPM1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 125/359 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as rs938379512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANK1 | c.972G>A p.Q324= | Splice Region (SNP) | VAF 10/344 reads (3%) | catalogued as rs1027918348; called by muse, mutect2
- FCHSD2 | c.1136G>C p.R379P | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60810109; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 139/528 reads (26%) | SIFT tolerated (0.42); catalogued as rs1566906430; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 19/62 reads (31%) | catalogued as rs754199513; called by mutect2, varscan2
- KCNT2 | c.2885A>C p.E962A | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV54075109, COSV99657123; called by muse, mutect2, varscan2
- LRRC56 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.443); catalogued as rs781714672; called by muse, varscan2
- MAEL | c.1118-2A>G p.X373_splice | Splice Site (SNP) | VAF 32/84 reads (38%) | catalogued as COSV63305146; called by mutect2, varscan2
- MYCBPAP | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs375348984; called by muse, mutect2, varscan2
- NPTN | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 136/399 reads (34%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.494); catalogued as rs1479052313, COSV54737649; called by muse, mutect2, varscan2
- OR2A7 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 80/938 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs774495113; called by muse, varscan2
- PTEN | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV64299225; called by muse, varscan2
- RARA | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54189681, COSV54192824; called by muse, mutect2, varscan2
- RTKN | c.886G>A p.V296M (on ENST00000272430 / NM_001015055.2; = p.V283M on NM_033046.2) | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs781348240; called by muse, mutect2, varscan2
- RYR1 | c.10184G>T p.R3395L | Missense Mutation (SNP) | VAF 150/364 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs543161252, COSV62093565; called by muse, mutect2, varscan2
- SLC4A1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 188/453 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM994551, COSV52260713; called by muse, mutect2, varscan2
- SYNE2 | c.17583G>A p.W5861* | Nonsense Mutation (SNP) | VAF 152/515 reads (30%) | catalogued as COSV59973960; called by muse, mutect2, varscan2
- SYNPO2 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 185/515 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs751491761; called by muse, mutect2, varscan2
- TRBV24-1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs556022715; called by muse, mutect2, varscan2
- USP8 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs371064052; called by muse, varscan2
- WSCD2 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 175/497 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs965481498, COSV54586388; called by muse, mutect2, varscan2
- ZBTB7B | c.115C>T p.R39W (on ENST00000292176; = p.R73W on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/350 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV52694695; called by muse, mutect2, varscan2
- ZBTB7C | c.450T>G p.D150E | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201996027; called by muse, mutect2, varscan2
- ABCB11 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANKRD11 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 28/724 reads (4%) | called by muse, mutect2
- ARID1A | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- ARID1A | c.2993_2994insT p.S999Qfs*8 | Frame Shift Ins (INS) | VAF 29/108 reads (27%) | called by mutect2, pindel
- CARMIL1 | c.3634+1G>A p.X1212_splice | Splice Site (SNP) | VAF 82/231 reads (35%) | called by muse, mutect2, varscan2
- CHM | c.1682G>A p.S561N | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTCF | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 71/186 reads (38%) | called by muse, mutect2, varscan2
- GABBR1 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HERC2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM2A | c.2278C>G p.R760G | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MAGEA12 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); called by muse, mutect2
- MFHAS1 | c.2050_2068del p.W684Afs*6 | Frame Shift Del (DEL) | VAF 61/217 reads (28%) | called by mutect2, pindel, varscan2
- NBEA | c.5103T>G p.S1701R | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NBPF12 | c.741_742del p.H248* | Frame Shift Del (DEL) | VAF 176/628 reads (28%) | called by pindel, varscan2
- OTC | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 19/634 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PARP10 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PLEKHO2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PLXNA3 | c.5479C>T p.L1827F | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTN | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2
- RNF183 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SALL3 | c.2069G>A p.C690Y | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SALL4 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 232/643 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SETD1B | c.2078del p.P693Hfs*31 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | called by mutect2, varscan2
- SETD1B | c.5693G>A p.G1898D | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFTPD | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TNRC18 | c.4496G>C p.R1499P | Missense Mutation (SNP) | VAF 121/332 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VCPIP1 | c.1580T>C p.V527A | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- ASCC2 | c.1371G>A p.A457= | Silent (SNP) | VAF 101/270 reads (37%) | catalogued as rs144678934; called by muse, mutect2, varscan2
- DMWD | c.1437C>T p.G479= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs770102643; called by muse, mutect2, varscan2
- ELOA3D | c.1047G>A p.P349= | Silent (SNP) | VAF 190/5304 reads (4%) | catalogued as rs750791538; called by muse, mutect2
- HELZ2 | c.6915G>T p.L2305= (on ENST00000467148 / NM_001037335.2; = p.L1736= on NM_033405.3) | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- KRTAP16-1 | c.714C>T p.C238= | Silent (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- LRRTM1 | c.1218C>T p.F406= | Silent (SNP) | VAF 81/232 reads (35%) | catalogued as rs769080308; called by muse, mutect2, varscan2
- MAP1A | c.3924G>A p.A1308= | Silent (SNP) | VAF 134/397 reads (34%) | catalogued as rs371287783; called by muse, mutect2, varscan2
- OSCP1 | c.1140C>T p.D380= (on ENST00000356637 / NM_001330493.1; = p.D370= on NM_145047.5) | Silent (SNP) | VAF 73/197 reads (37%) | catalogued as rs748276524, COSV52487938; called by muse, mutect2, varscan2
- PRDM5 | c.1620C>T p.T540= | Silent (SNP) | VAF 74/242 reads (31%) | catalogued as rs375097361; called by muse, mutect2, varscan2
- SYT3 | c.558T>C p.P186= | Silent (SNP) | VAF 78/248 reads (31%) | called by muse, mutect2, varscan2
- TIAM1 | c.4680G>T p.S1560= | Silent (SNP) | VAF 95/253 reads (38%) | called by muse, mutect2, varscan2
- WDFY4 | c.8784C>T p.F2928= | Silent (SNP) | VAF 64/196 reads (33%) | catalogued as rs529743311, COSV55434294; called by muse, mutect2, varscan2
- CD99L2 | c.-10G>T | 5'UTR (SNP) | VAF 84/255 reads (33%) | called by muse, mutect2, varscan2
- PPM1E | c.783+501T>A | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as rs1214151106; called by muse, mutect2, varscan2
- SNORD116-5 | n.63C>T | RNA (SNP) | VAF 117/403 reads (29%) | called by muse, mutect2, varscan2
- UBXN11 | c.-185C>T | 5'UTR (SNP) | VAF 8/124 reads (6%) | catalogued as rs1253673768, COSV100366293, COSV57488389; called by muse, mutect2
